Gene-level copy-number profile of tumor specimen ALCH-B368-TTP1-A from ALCHEMIST case ALCH-B368, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 64.4 years (23,531 days).
Specimen ALCH-B368-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0b606952-94bb-4152-b571-840cb599c196.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B368-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/7046e408-6370-4280-8a6b-9d8ca8010445

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 111; copy number 1: 21,175; copy number 2: 33,092; copy number 3: 2,821; copy number 4: 193; copy number 5: 759; copy number 6: 77; copy number 7: 39; copy number 8: 31; copy number 9: 25; copy number 10: 14; copy number 14: 61.

Homozygous deletions (total copy number 0; autosomes only): 111 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,555,639–2,569,888, 2 genes (within-gene range 0–1): TNFRSF14, AL139246.2.
- chr5:180,945,756–181,007,384, 6 genes (within-gene range 0–1): RPS29P12, AC091874.2, AC091874.1, ARPP19P1, BTNL3, RNU6-1036P.
- chr7:2,631,986–2,664,802, 1 gene: TTYH3.
- chr9:12,134–89,850, 7 genes: DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1.
- chr9:19,789,179–24,592,104, 85 genes (broad region; genes not listed).
- chr9:25,088,811–26,118,408, 5 genes: RN7SKP120, TUSC1, LINC01241, FAM71BP1, AL353753.1.
- chr9:42,707,800–42,714,539, 1 gene: BX664718.1.
- chr9:61,581,813–61,662,690, 4 genes: AL935212.3, FAM242D, Y_RNA, AL935212.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,006 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:46,243,548–48,269,838, 27 genes, copy number 5–6: AC104072.1, GABRA2, AC095060.1, RNU6-412P, RAC1P2, COX7B2, GABRA4, GABRB1, AC107398.3, COMMD8, AC107398.4, ATP10D, AC107398.1, AC107398.2, CORIN, MIR8053, AC092597.1, AC107068.2, AC107068.1, NFXL1, NIPAL1, CNGA1, TXK, RNU6-838P, U6, TEC, Y_RNA.
- chr5:58,198–32,791,724, 477 genes, copy number 5 (broad region; genes not listed).
- chr5:33,986,165–45,895,970, 185 genes, copy number 5 (broad region; genes not listed).
- chr10:5,346,651–8,515,106, 69 genes, copy number 5–6 (broad region; genes not listed).
- chr10:9,721,963–15,073,853, 95 genes, copy number 7–14 (broad region; genes not listed).
- chr10:25,813,811–29,318,328, 69 genes, copy number 6–9 (broad region; genes not listed).
- chr11:69,012,283–70,436,584, 42 genes, copy number 6–10: MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr12:66,302,493–67,670,919, 16 genes, copy number 5: HELB, GRIP1, OSBPL9P5, OSBPL9P4, AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1.
- chr12:69,212,108–70,243,379, 26 genes, copy number 5 (within-gene range 3–5): AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2.

Autosomal genes at a single copy (total copy number 1): 19,340. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
